Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H4-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis.
No evidence of malignancy.
- B. LIVER NODULE NO. 1, LEFT LOBE, CORE NEEDLE BIOPSY:
Liver parenchyma with focal scar.
No evidence of malignancy.
- C. LIVER NODULE NO. 2, LEFT LOBE, NEEDLE BIOPSY:
Liver parenchyma with focal scar.
No evidence of malignancy.
- D. PORTAL LYMPH NODE:
One lymph node (0/1), free of malignancy.
- E. RIGHT LOBE LIVER, PARTIAL RESECTION:
Hepatocellular carcinoma. See Key Pathologic Findings.

KEY PATHOLOGICAL FINDINGS:

Tumor type:	Hepatocellular carcinoma, moderately differentiated
Tumor configuration:	Circumscribed
Tumor size:	3.3 x 2.5 x 1.5 cm
Tumor necrosis:	Not identified
Extent of invasion:	Carcinoma is confined to within hepatic parenchyma
Vascular invasion:	Not identified
Perineural invasion:	Not identified
Parenchymal and surgical margins:	Free of malignancy
Additional findings:	Focal steatosis and portal triad chronic inflammation
Pathologic stage:	pT1 N0 M0

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by

Specimen(s) Received

- A GALLBLADDER
B LIVER NODULE #1 LEFT LOBE FS
C LIVER NODULE #2 LEFT LOBE FS
D PORTAL LYMPH NODES
E RIGHT LOBE LIVER

Clinical History

ICD-O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0
8170/3
JAS 4/28/14

[page 2 of 2]
HCC

Preoperative Diagnosis

HCC

Intraoperative Consultation

FSB1. LIVER NODULE, NO. 1, LEFT LOBE:
Benign liver with focal scar.

FSC1. LIVER NODULE, NO 2, LEFT LOBE:
Benign liver with focal scar.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by
in person at

I, _____ have performed the intraoperative consultation (s) and issued the above
diagnosis.

Gross Description

A. The specimen is received fresh labeled "gallbladder" and consists of a 7.7 x 2.8 x 2.5-cm intact gallbladder. The serosa is smooth and glistening. The wall averages 0.2 cm in thickness. The mucosa is velvety. No mass or other lesions are identified. The lumen contains a dark green viscous bile. No stones are identified. Representative sections are submitted as follows:

- A1: Cross section of cystic duct margin.
- A2: Random sections of gallbladder.

B. The specimen is received fresh for frozen section consultation labeled "liver nodule No. 1, left lobe," and consists of a 0.1-cm in diameter elongated portion of tan tissue which is 1.2 cm in length. The tissue is entirely frozen and submitted in FSB1.

C. The specimen is received fresh for intraoperative consultation labeled "liver nodule No. 2, left lobe," and consists of a 0.1-cm in diameter elongated portion of tan tissue which is 1.5 cm in length. The tissue is entirely frozen and submitted in FSC1.

D. The specimen is received fresh labeled "portal lymph nodes" and consists of a 1.9 x 1.4 x 0.9-cm firm tan lymph node with surrounding adipose tissue. The tissue is sectioned and entirely submitted in D1.

E. The specimen is received fresh labeled "right lobe liver" and consists of a 761.9-g, 17.5 x 16.0 x 7.0-cm lobe of liver. The surgical margin is inked black. The capsule is smooth and without adhesions. 3.8-cm from the closest surgical margin is a 3.3 x 2.5 x 1.5-cm well-circumscribed soft tan lobulated mass. The mass is 1.5 cm from the capsule. There is an additional soft discolored pale area adjacent to the mass. The remaining parenchyma is homogeneous tan without additional lesions. No frozen section is performed as per _____. A portion of the tissue is submitted to

Tissue Procurement Laboratory. Representative sections are submitted as follows:

- E1: Tissue adjacent to tissue submitted for tumor bank.
- E2: Margin closest to mass, perpendicular.
- E3-E4: Sections of mass.
- E5: Mass with surrounding normal parenchyma.
- E6: Separate pale lesion.
- E7: Normal parenchyma.

Source: NCI Genomic Data Commons file 6de3e2fb-df00-44ae-a728-ffb46bdb0fbc (TCGA-2Y-A9H4.8A93B07B-8DCC-4DF4-B792-212C80E203FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).